Surgical pathology report (de-identified scan), TCGA case TCGA-L5-A4OQ, project TCGA-ESCA (Esophageal Carcinoma), tissue source site University of Michigan, specimen TCGA-L5-A4OQ-01A (Primary Tumor).

[page 1 of 2]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 1
SEX: M

PROCEDURE: SPHS

Esophageal mass at 35-36 cm occupying 1/2 of esophagus.

PROCEDURE: SPGD

1. "Thoracic esophagus, proximal stomach, suture marks gastric margin. Please freeze entire margin, ? carcinoma, cardiac cancer." Tumor in GE junction. 3 cm from gastric staple line. Staple line removed and gastric margin shaved and entirely submitted. The previously opened segment is 12.2 cm in length. The esophageal margin is 2.5 cm in diameter, and the gastric margin is 6.6 cm. There is a small amount of adherent perigastric and periesophageal fat. The adventitia of the esophagus is focally firm. The gastric serosa is also focally firm. The esophageal adventitia is inked green and the gastric cardia serosa is inked black. Arising in the gastric mucosa and involving the GE junction is a 5.4 x 4 cm centrally ulcerated mass. Up to 1.7 cm appears to involve the esophageal side of the EG junction. The borders are raised and rolled. The firm, circular mass through the centrally ulcerated mass shows a maximum thickness of 1.4 cm with some penetration into the muscular wall. No evidence of perforating the gastric serosa is readily seen. Most of the ulcerating mass involves the gastric mucosa and underlying tissue. The small portion involving the esophageal mucosa shows no penetration to the adventitia. The remaining gastric serosa and mucosa are unremarkable. The remaining proximal esophageal mucosa and adventitia is unremarkable. Within the periesophageal and perigastric fat are lymph node candidates up to 1.9 cm in greatest dimensions. The cut surfaces of the larger lymph nodes are gray-white to tan and opaque.

1A. Frozen section control block shaved margin.

1B. Frozen section control block shaved margin.

1C-D. One shaved margin (1/2 in each). Frozen section control block.

1E. Frozen section control block 1 shaved margin.

1F-G. Sections of tumor to proximal.

1H-I. Tumor to lateral gastric mucosa.

1J. Tumor to distal mucosa.

1K. Ten whole lymph node candidates.

1L. Two bisected lymph node candidates. (1 inked black)

1M. Largest sectioned lymph node candidate.

2. "Cervical esophageal margin." Received in a small container of formalin is a 0.6 cm segment of esophageal tissue. There is a staple line along one margin and the opposing margin is opened. The adventitia and mucosa are unremarkable.

2A. Cervical esophageal margin. Staple line retained.

FROZEN SECTION REPORT

1. Negative for carcinoma.

1CD-0-3

Adenocarcinoma, NOS 8140/3
Site: esophageal, distal third C15.5

fw
10/9/12

[page 2 of 2]
PREVIOUS DIAGNOSIS INQUIRY

PAGE #: 2
SEX: M

[REDACTED] have reviewed and interpreted the frozen section material at the time it was requested.

Permanent sections confirm frozen section report.

PROCEDURE: SPWI

ESOPHAGUS CARCINOMA

LOCATION: Gastroesophageal junction

SIZE: 5.4 x 4.0 x 1.4 cm

HAS IT BEEN TREATED PREOPERATIVELY: No

TYPE OF CARCINOMA: Adenocarcinoma

DEPTH OF INVASION: Muscularis propria

NUMBER OF POSITIVE LYMPH NODES / TOTAL NUMBER OF NODES EXAMINED: 6/12

DISTANT METASTASIS: Unknown

RESECTION MARGIN INVOLVED: No

pT2 N1

PROCEDURE: SPDX

1 - 2. Gastroesophageal, resection: Invasive adenocarcinoma, extending into muscularis propria. Margins free. Please see template for details. Metastatic adenocarcinoma in six of twelve lymph nodes (6/12).

I, [REDACTED] the signing staff pathologist, have personally examined and interpreted the slides from this case.

Source: NCI Genomic Data Commons file 19190da1-4512-4512-9168-581c32060d0d (TCGA-L5-A4OQ.DF9FBECB-8BFD-472A-BC17-B3B65938E89F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).